Somatic mutation profile of tumor specimen TCGA-49-AAQV-01A (aliquot TCGA-49-AAQV-01A-11D-A397-08) from TCGA case TCGA-49-AAQV, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 64.0 years (23,370 days).
Specimen TCGA-49-AAQV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca188462-1ecc-4a87-9897-680ac7ce193f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AAQV-11A (Solid Tissue Normal), aliquot TCGA-49-AAQV-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68d530f4-0421-44fa-bf5b-6140a19d35a6

The open-access MAF lists 64 somatic variants for this specimen: 54 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 48, Silent 10, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATL2 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100184634; called by muse, mutect2, varscan2
- ATP12A | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54511941, COSV99517601; called by muse, mutect2, varscan2
- AVPR1A | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54546150, COSV54546332; called by muse, mutect2, varscan2
- CCNI | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV99423421; called by muse, mutect2
- CDC45 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.499); catalogued as rs750837444, COSV99596662; called by muse, mutect2, varscan2
- CNR1 | c.845T>A p.V282D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100759220; called by muse, mutect2, varscan2
- COL22A1 | c.4615+1G>T p.X1539_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as rs1333809746, COSV100276129, COSV100278383; called by muse, mutect2, varscan2
- CR1L | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs1446805290, COSV99687334; called by muse, mutect2
- CT83 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as COSV100902579, COSV100902605; called by muse, mutect2
- DCUN1D5 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.315); catalogued as COSV99499082; called by muse, mutect2
- DNAH8 | c.12632G>A p.G4211D | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV100545143; called by muse, mutect2, varscan2
- EIF4G2 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1364115405, COSV101150826; called by muse, mutect2, varscan2
- FOS | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206271705, COSV57839419; called by muse, mutect2
- GABRE | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100944270, COSV64820614; called by muse, mutect2, varscan2
- GTF3C1 | c.672G>T p.M224I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100649397; called by muse, mutect2, varscan2
- HDAC9 | c.1692A>C p.E564D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.444); catalogued as COSV101286767, COSV67777116; called by muse, mutect2
- HELQ | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV99787662; called by muse, mutect2
- HRH2 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99199632; called by muse, mutect2, varscan2
- ICA1L | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV100841768, COSV64173631; called by muse, mutect2
- KIAA0100 | c.4526G>T p.S1509I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101197306; called by muse, mutect2, varscan2
- KMT2D | c.4862C>T p.P1621L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99981503; called by muse, mutect2
- KRTAP10-5 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs201496484, COSV100555483; called by muse, mutect2
- LRIF1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100870839; called by muse, mutect2
- LYPD6B | c.67G>A p.A23T (on ENST00000409029 / NM_001317004.1; = p.A47T on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs369164244; called by muse, mutect2, varscan2
- MRPS27 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV99782198; called by muse, mutect2, varscan2
- MTUS1 | c.635A>G p.H212R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100029398; called by muse, mutect2, varscan2
- NIPBL | c.8392G>A p.A2798T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1029099152, COSV56946753; called by muse, mutect2
- NRK | c.3356G>A p.G1119D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99687708; called by muse, mutect2, varscan2
- NUP205 | c.5692G>C p.E1898Q | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99606977; called by muse, mutect2
- OR7A10 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.142); catalogued as COSV99932445; called by muse, mutect2
- OTUD6A | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610990; called by muse, mutect2, varscan2
- PAK3 | c.565G>A p.E189K (on ENST00000262836 / NM_001324328.2; = p.E174K on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99457340; called by muse, mutect2
- PAPOLA | c.381T>A p.S127R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV99354221; called by muse, mutect2, varscan2
- PAPOLA | c.1520del p.K507Sfs*9 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs1457905019; called by pindel, varscan2
- PLCH1 | c.1587C>G p.H529Q (on ENST00000340059 / NM_001130960.2; = p.H541Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV100396806; called by muse, mutect2, varscan2
- PNMA5 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.017); catalogued as COSV100721633; called by muse, mutect2
- PROX1 | c.1670C>G p.S557C | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV99799366; called by muse, mutect2, varscan2
- RAB28 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99986230; called by muse, mutect2, varscan2
- RAPGEF2 | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100031120; called by muse, mutect2
- SASH3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100795220; called by muse, mutect2
- SIPA1L2 | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99478190; called by muse, mutect2, varscan2
- SLC30A5 | c.784-1G>C p.X262_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | catalogued as COSV101173602; called by muse, mutect2
- SMAD3 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100529009; called by muse, mutect2
- SPOCD1 | c.2396C>T p.S799L | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1256916930, COSV57094638; called by muse, mutect2
- STYXL2 | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99609186; called by muse, mutect2
- SYNE1 | c.7993T>C p.S2665P (on ENST00000367255 / NM_182961.4; = p.S2672P on NM_033071.3) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV99563510; called by muse, mutect2, varscan2
- TFAP2D | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99145915; called by muse, mutect2, varscan2
- TTN | c.61931T>C p.V20644A (on ENST00000591111; = p.V13220A on NM_003319.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | PolyPhen possibly damaging (0.496); catalogued as COSV100611837; called by muse, mutect2
- ZNF425 | c.1326C>G p.F442L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV100955469; called by muse, mutect2
- ZSCAN30 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99734907; called by muse, mutect2
- EPB41L1 | c.2139_2149del p.E714Afs*9 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- MRC1 | c.2828C>G p.S943* | Nonsense Mutation (SNP) | VAF 11/315 reads (3%) | called by muse, mutect2
- PIGS | c.466del p.Q156Rfs*3 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- CYP3A5 | c.267G>A p.V89= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV56123164; called by muse, mutect2
- FLG | c.8782A>C p.R2928= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as COSV100911558, COSV64241743; called by muse, mutect2, varscan2
- GAA | c.711G>T p.A237= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV100163200; called by muse, mutect2, varscan2
- NPIPB15 | c.819C>A p.P273= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs1567418216, COSV101466005; called by muse, mutect2
- PSMA1 | c.240T>C p.D80= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101123657; called by muse, mutect2
- PTBP2 | c.297G>A p.L99= (on ENST00000426398 / NM_001300986.2; = p.L91= on NM_021190.4) | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100930155, COSV100930204; called by muse, mutect2
- SENP5 | c.1344C>G p.L448= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV100051985; called by muse, mutect2
- SPRY3 | c.84G>A p.V28= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs1446231927, COSV100249335; called by muse, mutect2, varscan2
- TRIM58 | c.486C>A p.A162= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100825079; called by muse, mutect2, varscan2
- VPS33A | c.375G>A p.L125= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs1212571590, COSV99931361; called by muse, mutect2
